TCGA case TCGA-13-0911 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8cad4217-5699-4735-9be3-fc0015a8d262

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Dead; Days to death: 1,355 days (3.7 years).

Diagnoses (3)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 55.5 years (20,276 days); Year of diagnosis: 2005; Method of diagnosis: Cytology; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No; Residual disease: R1.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 189 days; Number of cycles: 7; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 189 days; Number of cycles: 7; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 56.3 years (20,555 days); Days to diagnosis: 279 days; Prior treatment: Yes.
3. Progression of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 56.3 years (20,555 days); Days to diagnosis: 279 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 279 (post initial treatment): Progression or recurrence: Yes; Days to progression: 279 days; Evidence of progression type: Positive Biomarker(s).
- Days to follow up: 843 days (2.3 years); Disease response: With Tumor.
- Days to follow up: 1,355 days (3.7 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-13-0911-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.8.
  Slide TCGA-13-0911-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 100.
  Slide TCGA-13-0911-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 9; Percent stromal cells: 1; Percent lymphocyte infiltration: 10.
- Sample TCGA-13-0911-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid).
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form 1: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,355 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,355 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 279 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-13-0911-01A-01D-0399-01): tumor purity 0.6, ploidy 3.14, whole-genome doublings 1.
